TCGA case TCGA-BR-7901 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9b5e5122-8ea0-432c-bc64-932bf376fffd

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Ukraine; Age at index: 74 years; Vital status: Dead; Days to death: 105 days; Cause of death: Cancer Related.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.0; Tissue or organ of origin: Cardia, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 74.0 years (27,031 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 15.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Adenocarcinoma, NOS). Age at diagnosis: 74.3 years (27,122 days); Days to diagnosis: 91 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS to Locoregional Site.

Follow-up (3 entries)
- Days to follow up: 29 days; Disease response: Tumor Free.
- Day 91 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 91 days.
- Follow-up contact recording only the day: day 105.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BR-7901-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.5; Intermediate dimension: 1.6; Shortest dimension: 0.5.
  Slide TCGA-BR-7901-01A-01-BS1: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50.
  Slide TCGA-BR-7901-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50.
- Sample TCGA-BR-7901-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BR-7901-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Gastroesophageal Junction; Lymph nodes examined: Yes; Cancer procurement city: Kiev; Number of relatives with stomach cancer: 0.
- Follow-up form: Lost to follow-up: No; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Progressive Disease; Cause of death: Stomach Cancer.
- Follow-up form, New neoplasm event types: New tumor event type: Locoregional Recurrence.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 105 days; disease-specific survival: no event (censored), 105 days; disease-free interval: event (new tumor event after initially disease-free), 91 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 91 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BR-7901-01A-11D-2200-01): tumor purity 0.31, ploidy 4.69, whole-genome doublings 2.
